Gene-level copy-number profile of tumor specimen HCM-CSHL-0878-C18-06A from HCMI case HCM-CSHL-0878-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 53.1 years (19,396 days).
Specimen HCM-CSHL-0878-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d407cf2e-1879-49ff-8518-d5588be19da1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0878-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/4f6420a3-3b77-451f-9582-6f46c4f72b8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 724; copy number 1: 13,483; copy number 2: 43,730; copy number 3: 523; copy number 4: 122; copy number 5: 80; copy number 6: 2; copy number 7: 16; copy number 8: 37; copy number 9: 24; copy number 10: 50; copy number 11: 16; copy number 12: 29; copy number 13: 9; copy number 15: 14; copy number 19: 18; copy number 21: 8.

Homozygous deletions (total copy number 0; autosomes only): 212 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes (within-gene range 0–2): PRAMEF6, PRAMEF28P.
- chr1:13,060,869–13,062,229, 1 gene (within-gene range 0–1): HNRNPCL3.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr4:121,329,069–121,329,170, 1 gene: Y_RNA.
- chr8:64,091–1,708,476, 26 genes (within-gene range 0–2): AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1.
- chr8:12,115,767–12,177,550, 6 genes (within-gene range 0–1): FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr21:8,603,547–8,680,934, 2 genes: RPSAP68, CR381572.2.
- chr21:9,369,285–10,605,716, 20 genes (within-gene range 0–1): CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1, CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1.
- chr21:13,038,160–15,067,837, 61 genes (broad region; genes not listed).
- chr21:15,490,530–15,496,124, 2 genes: CYCSP42, AJ009632.1.
- chr21:15,694,300–22,116,605, 77 genes (broad region; genes not listed).
- chr22:18,178,038–18,530,573, 12 genes: FAM230D, GGTLC5P, FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 303 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,327,399–119,356,182, 1 gene, copy number 9 (within-gene range 2–9): LINC01780.
- chr1:119,368,779–119,394,130, 2 genes, copy number 9: HAO2, HAO2-IT1.
- chr1:206,957,965–206,970,625, 1 gene, copy number 5: FCAMR.
- chr8:37,326,575–37,849,861, 18 genes, copy number 6–7: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2.
- chr13:26,755,200–30,429,758, 76 genes, copy number 11–21 (broad region; genes not listed).
- chr20:24,679,547–26,251,546, 50 genes, copy number 10: AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2, MIR663AHG, AL121904.1, MIR663A.
- chr20:30,278,906–32,439,319, 66 genes, copy number 5 (broad region; genes not listed).
- chr20:33,980,679–34,123,290, 6 genes, copy number 9–11: RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1.
- chr20:37,693,955–38,729,372, 37 genes, copy number 8: CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1.
- chr20:40,685,848–41,383,107, 16 genes, copy number 9: MAFB, AL035665.1, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1.
- chr20:52,972,358–53,668,758, 14 genes, copy number 11–13: TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P.
- chr20:57,957,126–58,635,738, 13 genes, copy number 5: AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711.
- chr20:63,558,086–63,628,824, 3 genes, copy number 11: HELZ2, GMEB2, MHENCR.

Autosomal genes at a single copy (total copy number 1): 13,483. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
